Surgical pathology report (de-identified scan), TCGA case TCGA-J9-A8CN, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Melbourne Health, specimen TCGA-J9-A8CN-01A (Primary Tumor).

[page 1 of 2]
ONE ICD-O-3
path Adenocarcinoma, acinar 8140/3
Adenocarcinoma NOS 8140/3
Site Prostate NOS 861.9

DOB:

Sex:

Episode Results

1. - HIST
2. - VOLUMETRIC

Doctor Details

Requesting Doctor:

Copy-To Doctors:

Episode Details

Status:

Results Available:

Collection Date:

Reported Date:

Episode:

HISTOPATHOLOGY REPORT

CLINICAL NOTES :

Radical prostatectomy. Gleason 6, T1c.

MACROSCOPIC :

Labelled prostate. A prostate and attached seminal vesicles, 38 x 52 x 43 mm, and weighing 54g.

Block designation:

Right apex: A to D. Left apex: E to H. Right base: I to L. Left base: M to Q.

Apex to base, right: R to Y. Apex to base, left: Z to GG. P33

Tissue bank: Benign - right and left post PZ, apex and mid. Ca - right anterior apex TZ (confirmed on F/S).

MICROSCOPIC STRUCTURED REPORT : Carcinoma prostate

Specimen type : Robotic radical prostatectomy.

Index tumour:

Tumour type: Adenocarcinoma, transition zone type.

Site: Predominantly right anterior TZ with extension into the left TZ.

Gleason score: 3+3=6 with tertiary pattern 4

Tumour volume: 9.8cc

Other tumour foci:

Tumour type: Adenocarcinoma, transition zone type.

Site: Left TZ

[page 2 of 2]
Gleason score: 3+3=6

Tumour volume: 0.3cc

Perineural invasion : Present, multifocal

Lymphovascular invasion : Not identified.

Prostatic intraepithelial neoplasia : Present, high grade PIN

Extraprostatic extension : Right apical/mid anterolateral, 20mm, invading anterior fibromuscular stroma.

Seminal vesicle involvement : Not identified.

Pathological resection margin status : Positive, right apical/mid anterolateral, 1mm, in area of extraprostatic extension.

Lymph nodes : Not performed.

CONCLUSION

Robotic radical prostatectomy -- Bilateral prostate adenocarcinoma, index tumour right anterior transition zone, Gleason score 3+3=6 with tertiary pattern 4

Pathological stage -- pT3a.

Reported by

Rights Reserved.

Email:

Harmon Discrepancy		✓

Source: NCI Genomic Data Commons file f5d35e93-1bfd-4c27-9cf5-495776d7f6fd (TCGA-J9-A8CN.3D3F5AFD-4DA0-43EC-B6B9-D2F16B6206E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).